Somatic mutation profile of tumor specimen TARGET-10-PATITB-09A (aliquot TARGET-10-PATITB-09A-01D) from TARGET case TARGET-10-PATITB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.1 years (5,514 days).
Specimen TARGET-10-PATITB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f4c61d8-8d94-4261-ae65-7a5f30731163.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATITB-10A (Blood Derived Normal), aliquot TARGET-10-PATITB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1230b4ab-2b89-4781-9f22-fc4fef7700be

The open-access MAF lists 40 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, Intron 3, 3'UTR 3, Nonsense Mutation 3, In Frame Ins 2, Frame Shift Ins 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HUWE1 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557036757, COSV53341725; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRB3 | c.2929C>T p.R977W | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53256345; called by muse, mutect2, varscan2
- CRISP1 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100237090, COSV59993662; called by muse, mutect2, varscan2
- EZH2 | c.1942C>A p.Q648K (on ENST00000460911 / NM_001203247.2; = p.Q653K on NM_004456.5) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57450023, COSV57459965; called by muse, mutect2, varscan2
- FAM131A | c.607C>T p.R203C (on ENST00000310585; = p.R234C on NM_144635.5) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as rs1268490723, COSV55603487; called by muse, mutect2, varscan2
- JAK1 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61086725; called by muse, mutect2, varscan2
- JAK3 | c.2021T>C p.V674A | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV71685576; called by muse, mutect2
- MYOM1 | c.2273C>T p.S758L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs376205950; called by muse, varscan2
- NAGPA | c.1230C>G p.H410Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | PolyPhen benign (0.115); catalogued as rs779219438, COSV56570635; called by muse, varscan2
- NOTCH1 | c.5033T>A p.L1678Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- NOTCH1 | c.4776_4777insGAA p.F1592_L1593insE | In Frame Ins (INS) | VAF 6/29 reads (21%) | catalogued as COSV53052993; called by mutect2, pindel*
- PGLYRP1 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs1364126467, COSV50517337; called by muse, varscan2
- PHF6 | c.135C>A p.C45* | Nonsense Mutation (SNP) | VAF 17/25 reads (68%) | catalogued as COSV59705524; called by muse, mutect2, varscan2
- PTMA | c.190G>A p.E64K (on ENST00000341369 / NM_001099285.2; = p.E63K on NM_002823.5) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.171); catalogued as COSV58187895; called by muse, mutect2, varscan2
- RNF180 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV56964362; called by muse, mutect2, varscan2
- SLC13A1 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.786); catalogued as rs772776032, COSV52008597; called by muse, mutect2, varscan2
- SUZ12 | c.1552G>A p.G518R | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV100497032, COSV59500620; called by muse, mutect2, varscan2
- TENM4 | c.7255C>T p.R2419* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV53658382; called by muse, mutect2, varscan2
- TMEM14C | c.56C>G p.A19G | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV57639061; called by muse, mutect2, varscan2
- TRPM1 | c.3821G>A p.R1274Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs555450322, COSV56639859; called by muse, mutect2, varscan2
- USP7 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV61214098; called by muse, mutect2, varscan2
- IGHV3-20 | c.352_353insCACCTATTAACCCT | In Frame Ins (INS) | VAF 10/52 reads (19%) | called by mutect2, varscan2
- MUC3A | c.9809G>A p.W3270* | Nonsense Mutation (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- ZFAT | c.2757_2758insCAATGGT p.S920Qfs*3 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | called by mutect2, pindel, varscan2
- ALAS1 | c.1068C>T p.F356= | Silent (SNP) | VAF 5/39 reads (13%) | called by mutect2, varscan2
- BAG6 | c.3306G>A p.L1102= (on ENST00000676571; = p.L1055= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs1335167346; called by muse, mutect2, varscan2
- FBLN1 | c.84C>T p.D28= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs754024808, COSV53051778; called by muse, mutect2, varscan2
- ITGA1 | c.753T>C p.A251= | Silent (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- LGI3 | c.990C>T p.N330= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs763539802; called by muse, mutect2, varscan2
- MFAP2 | c.357C>T p.N119= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs369256913; called by muse, mutect2, varscan2
- OAS3 | c.243C>T p.L81= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs374581984; called by muse, mutect2, varscan2
- RAB3C | c.9C>T p.H3= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- HCN1 | c.*84G>T | 3'UTR (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- L3MBTL1 | c.361-111C>T | Intron (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- OSGIN1 | n.2013G>A | RNA (SNP) | VAF 9/20 reads (45%) | catalogued as rs145764374; called by muse, varscan2
- RNU6-516P | chr15:40528711 C>A | 5'Flank (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2
- SESN3 | c.*31G>C | 3'UTR (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- SOHLH2 | c.641+6787C>T | Intron (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- VEGFB | c.*89A>C | 3'UTR (SNP) | VAF 44/67 reads (66%) | called by muse, mutect2, varscan2
- WDR77 | c.870-134G>A | Intron (SNP) | VAF 6/24 reads (25%) | catalogued as rs113907322; called by muse, mutect2
